Gene-level copy-number profile of tumor specimen TCGA-AA-A01T-01A from TCGA case TCGA-AA-A01T, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage III; Age at diagnosis: 63.5 years (23,192 days).
Specimen TCGA-AA-A01T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.4a24a2a7-a6a0-4a41-a1df-595c3aaff584.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A01T-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4cf2aa59-b794-4bda-96a9-4f23dbee54c7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 703; copy number 2: 5,204; copy number 3: 23,992; copy number 4: 19,938; copy number 5: 6,991; copy number 6: 2,090; copy number 7: 115; copy number 8: 787.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A01T-01A-21D-A080-01): tumor purity 0.71, ploidy 3.64, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 902 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:87,503,017–87,713,323, 1 gene, copy number 7 (within-gene range 5–7): ABCB1.
- chr7:87,627,548–95,324,532, 114 genes, copy number 7 (broad region; genes not listed).
- chr20:33,728,931–64,313,132, 787 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 703. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
